Somatic mutation profile of tumor specimen MMRF_2499_1_BM_CD138pos (aliquot MMRF_2499_1_BM_CD138pos_T1_KHS5U_K15129) from MMRF case MMRF_2499, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.1 years (20,130 days).
Specimen MMRF_2499_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b0d0cca-5d92-411a-baa2-949d908744ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2499_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2499_1_PB_Whole_C3_KHS5U_K15128; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71925d8e-68ec-48cf-bc7d-7c6edf91af21

The open-access MAF lists 91 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 25, Silent 14, Intron 8, 5'UTR 3, Frame Shift Del 2, 5'Flank 1, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 143/440 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP10A | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs150976669; called by muse, mutect2, varscan2
- CDK20 | c.607del p.L203Ffs*104 (on ENST00000325303 / NM_001039803.3; = p.L182Ffs*104 on NM_012119.4) | Frame Shift Del (DEL) | VAF 59/211 reads (28%) | catalogued as COSV100308153; called by mutect2, pindel, varscan2
- H1-5 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 89/173 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388483978, COSV58898911, COSV58899545; called by muse, mutect2, varscan2
- IGHV2-70 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs373599438; called by muse, varscan2
- ITIH6 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs780083076; called by muse, mutect2, varscan2
- LILRA2 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1413299457; called by muse, mutect2, varscan2
- LPAR3 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs528568658; called by muse, mutect2, varscan2
- LSS | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777582592; called by muse, mutect2
- MIA3 | c.3409G>T p.A1137S | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV60514851; called by muse, mutect2
- OR4Q3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59179991; called by muse, mutect2
- PLCH2 | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs768338940; called by muse, mutect2, varscan2
- PROX2 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 61/117 reads (52%) | catalogued as COSV71520096; called by muse, mutect2, varscan2
- SLC4A8 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749258561, COSV60650775; called by muse, mutect2
- TTC31 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs368112249, COSV52037578, COSV99281881; called by muse, mutect2, varscan2
- ARCN1 | c.46A>C p.I16L | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2
- CCDC7 | c.3369C>A p.H1123Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CD83 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLIP4 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2
- COBL | c.2468A>C p.H823P | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE4 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DTX4 | c.353A>C p.E118A | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FAM131B | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 13/389 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- GOLGA6L2 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IGHV2-70D | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, varscan2
- ITGA10 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MPDZ | c.3156C>G p.D1052E | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MRPS30 | c.942A>C p.Q314H | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); called by muse, mutect2
- MX1 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRDC | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PFKFB1 | c.698A>G p.Q233R | Missense Mutation (SNP) | VAF 38/116 reads (33%) | PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RCC1L | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RPL14 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.587); called by muse, mutect2
- SMARCB1 | c.76T>A p.Y26N | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- TAFA4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- TENT5C | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- USP43 | c.2172C>A p.G724= | Splice Region (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- WDR45 | c.984del p.D329Mfs*81 (on ENST00000376372 / NM_001029896.2; = p.D330Mfs*81 on NM_007075.3) | Frame Shift Del (DEL) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- ZNF283 | c.1483A>T p.T495S | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- ANKHD1 | c.7581C>T p.G2527= | Silent (SNP) | VAF 150/383 reads (39%) | called by muse, mutect2, varscan2
- B3GNT8 | c.1116G>A p.L372= | Silent (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.669G>A p.A223= | Silent (SNP) | VAF 95/178 reads (53%) | catalogued as rs1283171737; called by muse, mutect2, varscan2
- CALML5 | c.135G>A p.S45= | Silent (SNP) | VAF 77/189 reads (41%) | called by muse, mutect2, varscan2
- CCNL1 | c.90G>A p.T30= | Silent (SNP) | VAF 129/390 reads (33%) | called by muse, mutect2, varscan2
- CEP350 | c.960C>T p.N320= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV62485847; called by muse, mutect2, varscan2
- CETN2 | c.447T>C p.A149= | Silent (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- CSF3R | c.504G>A p.Q168= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs775698906, COSV58972046; called by muse, mutect2, varscan2
- DOCK7 | c.4050T>C p.D1350= (on ENST00000635253 / NM_001367561.1; = p.D1319= on NM_033407.3) | Silent (SNP) | VAF 58/146 reads (40%) | called by muse, mutect2, varscan2
- HMOX1 | c.471G>C p.L157= | Silent (SNP) | VAF 24/223 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.198G>A p.L66= | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as rs562646171; called by muse, varscan2
- PCLO | c.6441C>G p.T2147= | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as COSV61638397; called by muse, mutect2, varscan2
- SMS | c.930G>T p.G310= | Silent (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- UTP3 | c.513C>A p.R171= | Silent (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- A4GNT | c.*196A>G | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- ADAMTS5 | c.*301C>A | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- ATL3 | c.*2692C>G | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- CDH8 | c.*1421G>T | 3'UTR (SNP) | VAF 8/90 reads (9%) | catalogued as rs1223229949; called by muse, mutect2
- CERS3 | c.*543T>C | 3'UTR (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- COL27A1 | c.*802C>G | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- CTSV | c.*57C>G | 3'UTR (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- EIPR1 | c.516+6011G>T | Intron (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+1113A>C | Intron (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- FLRT3 | c.*1284G>A | 3'UTR (SNP) | VAF 38/97 reads (39%) | catalogued as rs1457876086; called by muse, mutect2, varscan2
- FSTL4 | c.*2601C>A | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- HEATR1 | c.*768dup | 3'UTR (INS) | VAF 40/80 reads (50%) | called by mutect2, varscan2
- IGLL5 | c.-71G>A | 5'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
- KCNQ2 | c.1247+67G>A | Intron (SNP) | VAF 115/269 reads (43%) | catalogued as rs199855727; called by muse, mutect2, varscan2
- LILRB3 | c.*207C>G | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- LINGO2 | c.*497T>A | 3'UTR (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- LMO3 | c.*1073T>G | 3'UTR (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- MGAT5 | c.*3406G>C | 3'UTR (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- MROH7 | c.2964+2032C>T | Intron (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- MRPS27 | c.*448C>T | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- MRPS27 | c.*447G>C | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- NPAS3 | c.1153+2123A>C | Intron (SNP) | VAF 174/403 reads (43%) | called by muse, mutect2, varscan2
- PHACTR2 | c.*4015T>G | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2
- RNF217-AS1 | n.2811G>A | RNA (SNP) | VAF 28/58 reads (48%) | catalogued as rs763875292; called by muse, mutect2, varscan2
- S100B | c.*344T>C | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- SARAF | c.-70C>T | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- SFN | c.*162del | 3'UTR (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- SIX4 | c.-79G>C | 5'UTR (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- SLC50A1 | chr1:155135384 T>C | 5'Flank (SNP) | VAF 38/98 reads (39%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*3447C>G | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- STOML2 | c.*3G>T | 3'UTR (SNP) | VAF 12/180 reads (7%) | catalogued as rs1258313431; called by muse, mutect2
- TENT5D | c.*1428C>G | 3'UTR (SNP) | VAF 4/96 reads (4%) | catalogued as COSV100382515; called by muse, mutect2
- TSSK1B | c.*380G>A | 3'UTR (SNP) | VAF 10/198 reads (5%) | catalogued as rs946048135, COSV101181182; called by muse, mutect2
- ULK1 | c.2684+36G>A | Intron (SNP) | VAF 30/55 reads (55%) | catalogued as rs377160205; called by muse, mutect2, varscan2
- XPO5 | c.*460T>C | 3'UTR (SNP) | VAF 40/91 reads (44%) | catalogued as rs888147021; called by muse, mutect2, varscan2
- XPO5 | c.*173T>C | 3'UTR (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- XPO5 | c.3066+90T>G | Intron (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- XPO5 | c.3066+89T>A | Intron (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
